Somatic mutation profile of tumor specimen HTMCP-03-06-02345-01A (aliquot HTMCP-03-06-02345-01A-01D-9392) from CGCI case HTMCP-03-06-02345, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 57.9 years (21,138 days).
Specimen HTMCP-03-06-02345-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52c6596e-7382-4e38-8c3a-18dd7e16489f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02345-10A (Blood Derived Normal), aliquot HTMCP-03-06-02345-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3540a115-f431-472f-80fe-267c6ff5b270

The open-access MAF lists 30 somatic variants for this specimen: 20 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 18, Silent 10, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM2B | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV100312679; called by muse, varscan2
- BCOR | c.578A>G p.N193S | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs1259098035; called by muse, mutect2, varscan2
- GREB1L | c.5707G>A p.E1903K | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1168976920, COSV52562559; called by muse, mutect2
- GRIA3 | c.2077-1G>A p.X693_splice | Splice Site (SNP) | VAF 10/69 reads (14%) | catalogued as COSV52051365; called by muse, mutect2, varscan2
- MAGEC2 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV56000605; called by muse, mutect2
- MYH7 | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs1437377039; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR4S1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs185370970, COSV100180201, COSV100180333; called by muse, mutect2, varscan2
- PLEC | c.11242G>A p.G3748S (on ENST00000322810 / NM_201380.4; = p.G3638S on NM_000445.5) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201595670; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCA4 | c.3181G>A p.E1061K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV60803781; called by muse, mutect2, varscan2
- ST18 | c.1734C>G p.I578M | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52513180, COSV99389679; called by muse, mutect2, varscan2
- TOX | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1416687673; called by muse, mutect2, varscan2
- DHX16 | c.2804A>C p.D935A | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ELAPOR1 | c.667A>T p.T223S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- FAM200B | c.1846T>C p.S616P | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM47B | c.926C>G p.P309R | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HLA-B | c.288_289del p.Q96Hfs*2 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- LRRC34 | c.898G>T p.D300Y (on ENST00000446859 / NM_001172779.2; = p.D268Y on NM_153353.5) | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRRCC1 | c.1151A>G p.Y384C | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- PNN | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.958); called by muse, mutect2
- ZNF536 | c.2888C>T p.S963F | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ADAMTS2 | c.573C>T p.I191= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs774498509, COSV99206595; called by mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1656G>A p.T552= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as rs781718047, COSV62568311; called by muse, mutect2, varscan2
- IMPG2 | c.558T>C p.P186= | Silent (SNP) | VAF 11/161 reads (7%) | called by muse, mutect2
- ITGA7 | c.3372G>A p.A1124= (on ENST00000555728; = p.A1080= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs1026883316, COSV57701725; called by muse, mutect2, varscan2
- LINGO4 | c.1614C>T p.V538= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs531705100, COSV63214848; called by muse, mutect2, varscan2
- NLRP8 | c.2499G>A p.A833= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as rs368088277; called by muse, mutect2, varscan2
- PLCD1 | c.1326C>T p.L442= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs150254083; called by mutect2, varscan2
- SPEG | c.999G>A p.T333= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as rs1455001204, COSV56662340; called by muse, mutect2
- SYNM | c.2520G>A p.G840= | Silent (SNP) | VAF 26/112 reads (23%) | called by muse, mutect2, varscan2
- ZNF577 | c.936C>T p.D312= | Silent (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
